Gene-level copy-number profile of tumor specimen MP2PRT-PARCBE-TMP1-A from MP2PRT case MP2PRT-PARCBE, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lymphoid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.0 years (1,823 days).
Specimen MP2PRT-PARCBE-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 40b6e321-4fab-4bac-87f7-9b7c83847a7e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PARCBE-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,233 have no estimate.
https://portal.gdc.cancer.gov/files/dddedf6e-c2a1-4a57-916e-fbb7b7fecb8b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 320; copy number 1: 2,387; copy number 2: 54,969; copy number 3: 714.

Homozygous deletions (total copy number 0; autosomes only): 320 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,857,161–89,297,785, 45 genes (within-gene range 0–2): IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30, IGKV3-31, IGKV1-32, IGKV1-33, IGKV3-34, IGKV1-35, IGKV2-36, IGKV1-37.
- chr2:89,968,867–90,022,185, 7 genes: IGKV1D-27, IGKV2D-26, IGKV3D-25, IGKV2D-24, IGKV2D-23, IGKV1D-22, IGKV6D-21.
- chr2:90,114,838–90,173,414, 4 genes (within-gene range 0–2): IGKV3D-15, IGKV2D-14, IGKV1D-12, IGKV3D-11.
- chr2:113,325,372–113,425,548, 1 gene (within-gene range 0–2): AC016745.1.
- chr10:1,526,637–1,556,984, 1 gene (within-gene range 0–2): ADARB2-AS1.
- chr14:22,168,429–22,552,156, 88 genes (within-gene range 0–2) (broad region; genes not listed).
- chr14:105,672,308–106,771,020, 162 genes (within-gene range 0–2) (broad region; genes not listed).
- chr22:22,168,289–22,245,515, 12 genes: AC245517.2, SOCS2P2, IGLVIV-59, IGLVV-58, BMP6P1, IGLV6-57, IGLVI-56, IGLV11-55, IGLVIV-53, TOP3BP1, AC245060.3, VPREB1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 2,387. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
